Gene-level copy-number profile of tumor specimen AP-JKPX-9R from APOLLO case AP-JKPX, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2.
Specimen AP-JKPX-9R: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a942585f-b1f7-4816-85e5-caf863cfe186.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-JKPX-FG (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/ac6671b7-33b5-4b85-ace2-11722fd6e056

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,873; copy number 2: 24,533; copy number 3: 21,883; copy number 4: 7,186; copy number 5: 710; copy number 6: 55; copy number 7: 81; copy number 8: 1; copy number 9: 61; copy number 10: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 867 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:70,954,708–72,279,503, 21 genes, copy number 6–7 (within-gene range 2–7): FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1.
- chr5:58,198–1,708,868, 61 genes, copy number 5 (broad region; genes not listed).
- chr5:17,065,598–17,486,829, 15 genes, copy number 5 (within-gene range 3–5): BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218.
- chr5:34,373,028–39,572,639, 87 genes, copy number 5–6 (broad region; genes not listed).
- chr7:141,652,381–159,233,377, 449 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:73,358,670–73,441,526, 2 genes, copy number 5 (within-gene range 3–5): AC111149.2, STAU2-AS1.
- chr12:24,566,964–27,824,382, 82 genes, copy number 5 (broad region; genes not listed).
- chr12:73,648,666–73,846,188, 4 genes, copy number 10: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–73,919,337, 1 gene, copy number 10: AC136188.1.
- chr14:34,485,979–37,596,059, 83 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr14:49,768,130–50,105,043, 15 genes, copy number 7 (within-gene range 4–7): KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1.
- chr20:30,214,765–30,403,384, 8 genes, copy number 5: CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1.
- chr20:50,479,767–50,585,879, 6 genes, copy number 5: COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645.
- chr20:62,640,719–62,643,304, 1 gene, copy number 5 (within-gene range 4–5): AL357033.1.
- chr22:38,200,767–38,794,143, 32 genes, copy number 8–9 (within-gene range 2–9): MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E, TPTEP2, Z98749.1, Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A, CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22, JOSD1, GTPBP1, PRDX3P1, AL021707.5, SUN2, AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7.

Autosomal genes at a single copy (total copy number 1): 3,869. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
